Somatic mutation profile of tumor specimen 0DWGJM from CCDI case PBCPEA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Desmoplastic nodular medulloblastoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 13.0 years (4,765 days).
Specimen 0DWGJM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 958af92f-10b5-46ad-bf21-bc49cd112cd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWGJ7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6211b9d-314d-403f-a964-93c5064c3260

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Frame Shift Del 2, Frame Shift Ins 2, Silent 2, Splice Site 1, Intron 1, 3'UTR 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COBLL1 | c.974C>T p.S325L (on ENST00000392717; = p.S287L on NM_014900.5) | Missense Mutation (SNP) | VAF 294/723 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776965929; called by muse, mutect2, varscan2
- CTNS | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 228/490 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs139585545; called by muse, mutect2, varscan2
- PRPF40A | c.2123G>A p.R708H | Missense Mutation (SNP) | VAF 183/489 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1316705398; called by muse, mutect2, varscan2
- CMTR1 | c.1330del p.V444Wfs*6 | Frame Shift Del (DEL) | VAF 105/224 reads (47%) | called by mutect2, varscan2
- DNAJC28 | c.1109_1113del p.K370Rfs*13 | Frame Shift Del (DEL) | VAF 118/367 reads (32%) | called by mutect2, varscan2
- KDM6A | c.327T>G p.Y109* | Nonsense Mutation (SNP) | VAF 199/212 reads (94%) | called by muse, mutect2, varscan2
- LRIT1 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LRRC14 | c.599T>A p.L200Q | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NCOA7 | c.66dup p.Q23Tfs*23 | Frame Shift Ins (INS) | VAF 170/372 reads (46%) | called by mutect2, varscan2
- PTCH1 | c.302dup p.V103Gfs*37 | Frame Shift Ins (INS) | VAF 479/509 reads (94%) | called by mutect2, varscan2
- SZT2 | c.3670G>T p.A1224S (on ENST00000634258 / NM_001365999.1; = p.A1167S on NM_015284.4) | Missense Mutation (SNP) | VAF 171/356 reads (48%) | SIFT tolerated (0.78); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- XPO1 | c.1245+1G>A p.X415_splice | Splice Site (SNP) | VAF 220/476 reads (46%) | called by muse, mutect2, varscan2
- VWF | c.1542C>T p.P514= | Silent (SNP) | VAF 175/379 reads (46%) | catalogued as rs1374807995; called by muse, mutect2, varscan2
- ZFHX3 | c.30G>A p.S10= | Silent (SNP) | VAF 242/542 reads (45%) | catalogued as rs570955376; called by muse, mutect2, varscan2
- GPR4 | c.-13C>T | 5'UTR (SNP) | VAF 22/48 reads (46%) | catalogued as rs774556168; called by muse, mutect2, varscan2
- NOP9 | c.*2634C>T | 3'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, varscan2
- TTC14 | c.1290+107A>G | Intron (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
